Somatic mutation profile of tumor specimen TCGA-BP-4973-01A (aliquot TCGA-BP-4973-01A-01D-1462-08) from TCGA case TCGA-BP-4973, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 47.8 years (17,461 days).
Specimen TCGA-BP-4973-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33f4984c-866f-4c4a-a7f3-5fd45c5e6aef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4973-11A (Solid Tissue Normal), aliquot TCGA-BP-4973-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75916aa3-0a4c-4dc5-b2d4-46d1844a0e34

The open-access MAF lists 31 somatic variants for this specimen: 28 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 20, Silent 3, Splice Site 2, Frame Shift Ins 2, Frame Shift Del 2, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.6098G>C p.R2033T | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.923); catalogued as COSV67988720; called by muse, mutect2, varscan2
- COL8A2 | c.664G>T p.G222W | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as COSV100290948, COSV57442314; called by muse, mutect2, varscan2
- CTNNB1 | c.1276A>G p.N426D | Missense Mutation (SNP) | VAF 89/194 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62705940; called by muse, mutect2, varscan2
- DOCK2 | c.4082T>A p.F1361Y | Missense Mutation (SNP) | VAF 104/424 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56968068; called by muse, mutect2, varscan2
- FLNC | c.3109A>G p.K1037E | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.97); PolyPhen benign (0.158); catalogued as COSV57958432; called by muse, mutect2, varscan2
- HAS1 | c.1705C>T p.R569W | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV55788251; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1457C>A p.A486D | Missense Mutation (SNP) | VAF 116/391 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as COSV57132052, COSV57132722; called by muse, mutect2, varscan2
- KATNIP | c.1321G>T p.V441F | Missense Mutation (SNP) | VAF 49/162 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.257); catalogued as COSV55175368, COSV55184532, COSV99849736; called by muse, mutect2, varscan2
- NBEA | c.7702C>T p.H2568Y | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs992856242, COSV59797431; called by muse, mutect2
- NPHP3 | c.1774C>A p.L592M | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV58631340; called by muse, mutect2, varscan2
- NUP210L | c.2436T>G p.N812K | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as COSV55150886; called by muse, mutect2, varscan2
- OR4C12 | c.751C>G p.P251A | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV58860033, COSV58860399; called by muse, mutect2
- PBRM1 | c.2126T>C p.I709T | Missense Mutation (SNP) | VAF 77/147 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV56285054, COSV56294293; called by muse, mutect2, varscan2
- PCDHB15 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.026); catalogued as COSV51048049; called by muse, mutect2, varscan2
- PLXNB2 | c.4433C>T p.P1478L | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs200623878; called by muse, mutect2, varscan2
- PNLIP | c.1203T>A p.N401K | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1272704083, COSV65041009; called by muse, mutect2, varscan2
- PTPRJ | c.2617G>T p.D873Y | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV69250194, COSV69253020; called by muse, mutect2, varscan2
- RBPJ | c.672C>T p.L224= | Splice Region (SNP) | VAF 63/181 reads (35%) | catalogued as COSV60753209; called by muse, mutect2, varscan2
- SEMA6D | c.434G>T p.C145F | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60379724; called by muse, mutect2, varscan2
- SLIT3 | c.4127+1G>C p.X1376_splice | Splice Site (SNP) | VAF 25/49 reads (51%) | catalogued as COSV60617452; called by muse, mutect2, varscan2
- TNC | c.3925C>T p.R1309C | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs975197014, COSV60786586; called by muse, mutect2, varscan2
- URB2 | c.3437C>T p.T1146M | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs141779194; called by muse, mutect2, varscan2
- ARHGAP29 | c.2247_2247+3del p.X749_splice | Splice Site (DEL) | VAF 69/201 reads (34%) | called by mutect2, pindel, varscan2
- ATMIN | c.1664_1671del p.L555* | Frame Shift Del (DEL) | VAF 27/91 reads (30%) | called by mutect2, pindel, varscan2
- CYFIP1 | c.312_313del p.R104Sfs*14 | Frame Shift Del (DEL) | VAF 54/268 reads (20%) | called by pindel, varscan2
- HSP90AB1 | c.1345dup p.R449Pfs*5 | Frame Shift Ins (INS) | VAF 33/132 reads (25%) | called by mutect2, pindel, varscan2
- NEDD9 | c.2216dup p.R740Afs*80 | Frame Shift Ins (INS) | VAF 44/166 reads (27%) | called by pindel, varscan2
- PERP | c.498_512del p.A167_C171del | In Frame Del (DEL) | VAF 7/42 reads (17%) | called by mutect2, pindel, varscan2
- ATP10B | c.1347C>T p.T449= | Silent (SNP) | VAF 26/330 reads (8%) | catalogued as rs1178439671, COSV58779421; called by muse, mutect2
- KEAP1 | c.315T>C p.P105= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as rs377493095, COSV50308058; called by muse, mutect2, varscan2
- ZNF223 | c.615G>A p.K205= | Silent (SNP) | VAF 127/300 reads (42%) | catalogued as rs1352402037, COSV71571945; called by muse, mutect2, varscan2
